National Lung Screening Trial (NLST) participant 130642 — screening results and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 55 years; Gender: female; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; no CT screening exam record exists for this participant — in this public subset that is the pattern of the chest-radiography arm: every CT screen with a result has an exam record, and the subset has no trial-arm field)
- T0 (day 0): Negative screen, no significant abnormalities.
- T1 (day 366): Negative screen, no significant abnormalities.
- T2 (day 765): Negative screen, minor abnormalities not suspicious for lung cancer.

Lung cancer (1 primary lung cancer record; the first confirmed lung cancer occurred after the screening years; study year of the first confirmed lung cancer: T6; the diagnosis is not linked to a positive screen by the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 2,318, study year T6. Site: lower lobe of lung (ICD-O-3 C34.3), determined from histology. Primary tumour location: left lower lobe. Histology: squamous cell carcinoma, NOS (ICD-O-3 8070/3). Grade: well differentiated (G1). Tumour size on pathology: 28 mm. AJCC 6th edition staging: stage IA (best stage, from clinical TNM); clinical T1 N0 M0 (stage IA); a stage recorded on the form without separate T, N, M: stage IV. AJCC 7th edition staging: stage IA; clinical T1b N0 M0.

Follow-up
Last known free of lung cancer: day 2,165.
